Gene-level copy-number profile of tumor specimen TCGA-MX-A666-01A from TCGA case TCGA-MX-A666, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,288 days).
Specimen TCGA-MX-A666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.eae2f5db-c9c7-47aa-b447-b0479d18ea2b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MX-A666-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5c1fe3cc-3832-4b0d-9297-45dab51a40ba

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 30,400; copy number 2: 24,871; copy number 3: 3,485; copy number 4: 854; copy number 5: 125; copy number 6: 53; copy number 7: 10; copy number 8: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MX-A666-01A-11D-A31K-01): tumor purity 0.38, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,493,345–4,847,840, 3 genes (within-gene range 0–1): ITPR1, EGOT, AC018816.2.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,543 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–167,022,214, 945 genes, copy number 3–5 (broad region; genes not listed).
- chr1:248,197,265–248,919,946, 40 genes, copy number 3: OR2M3, OR2M4, OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:38,814–49,879,363, 836 genes, copy number 3–7 (broad region; genes not listed).
- chr5:3,357,264–19,234,487, 266 genes, copy number 3–7 (broad region; genes not listed).
- chr6:4,049,434–4,189,806, 7 genes, copy number 3 (within-gene range 2–3): FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1.
- chr6:4,341,756–4,383,597, 2 genes, copy number 3: AL159166.1, AL162718.3.
- chr8:64,973,488–144,143,664, 1,194 genes, copy number 3 (broad region; genes not listed).
- chr10:60,869,438–61,026,420, 3 genes, copy number 3: RHOBTB1, RNU2-72P, LINC00845.
- chr12:31,105,105–32,383,633, 49 genes, copy number 3–8 (within-gene range 2–8): AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2.
- chr12:51,281,038–51,812,864, 8 genes, copy number 3 (within-gene range 2–3): BIN2, CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10, AC068987.1.
- chr16:85,227,203–85,352,961, 5 genes, copy number 3 (within-gene range 2–3): AC092275.1, COX6CP16, LINC00311, MIR5093, AC092377.1.
- chr17:28,944,796–29,551,903, 21 genes, copy number 3 (within-gene range 2–3): AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P.
- chr17:41,467,956–42,021,376, 32 genes, copy number 3 (within-gene range 2–3): RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25, CNP, DNAJC7.
- chr18:20,946,906–33,751,195, 208 genes, copy number 3 (broad region; genes not listed).
- chr18:57,961,231–58,019,061, 2 genes, copy number 3: LINC01897, HMGN1P30.
- chr19:12,945,855–16,628,204, 181 genes, copy number 3–5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:20,122,569–20,321,305, 1 gene, copy number 4 (within-gene range 1–4): AC011447.3.
- chr19:20,167,214–21,060,050, 37 genes, copy number 4: ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5, ZNF826P, BNIP3P20, AC078899.2, MIR1270, BNIP3P22, AC008554.1, BNIP3P23, ZNF737, AC010636.2, VN1R78P, AC010636.1, ZNF626, AC010329.5, AC010329.2, AC010329.1, VN1R79P, ZNF66, BNIP3P24, AC008739.2, ZNF85, AC008739.6, KRT18P40, AC008739.1, ZNF430, AC008739.3.
- chr19:23,739,195–34,426,168, 164 genes, copy number 3–6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:43,894,720–45,547,752, 68 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr20:45,881,227–64,313,132, 452 genes, copy number 4 (broad region; genes not listed).
- chr21:41,361,999–41,717,975, 11 genes, copy number 4: MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112.
- chr22:30,080,464–30,299,482, 11 genes, copy number 3 (within-gene range 1–3): HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1.

Autosomal genes at a single copy (total copy number 1): 27,979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
